Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A49A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A49A-01A (Primary Tumor).

[page 1 of 8]
Pathology Report

FINAL

Report Type Pathology Report
Date of Event
Sex M
Authored by
Hosp/Group
Record Status FINAL

FINAL DIAGNOSIS:

PART 1: MAXILLA, RIGHT, RIGHT MAXILLECTOMY

A. INVASIVE MODERATELY DIFFERENTIATED KERATIZING SQUAMOUS CELL CARCINOMA OF HARD AND SOFT PALATES (5.5 CM).

B. NO ANGIOLYMPHATIC INVASION OR PERINEURAL INVASION IDENTIFIED.

C. ALL TRUE BONE AND SOFT TISSUE RESECTION MARGINS ARE FREE OF TUMOR. (

SEE PARTS 4, 7, 8, 9, 10 AND 11)

D. PATHOLOGIC STAGE: pT4b, N0.

PART 2: CONTENTS OF PTERYGOPALATINE FOSSA, RIGHT, EXCISION

A. BONE WITH REACTIVE CHANGES AND SOFT TISSUE.

B. NO TUMOR PRESENT.

PART 3: INFRAORBITAL NERVE, RIGHT, EXCISION

A. UNREMARKABLE NERVE.

B. NO TUMOR PRESENT.

PART 4: MARGIN, RIGHT PTERYGOID, BIOPSY

NO TUMOR PRESENT.

PART 5: NASOPHARYNX, BIOPSY

NO TUMOR PRESENT.

PART 6: MUSCLE, RIGHT PTERYGOID, BIOPSY

MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA INVOLVING

MUSCLE AND BONE.

PART 7: MARGIN, LEFT LIP, BIOPSY

NO TUMOR PRESENT.

PART 8: MARGIN, RIGHT LIP, BIOPSY

NO TUMOR PRESENT.

PART 9: MARGIN, LEFT HARD PALATE, BIOPSY

NO TUMOR PRESENT.

PART 10: MARGIN, SOFT PALATE, BIOPSY

NO TUMOR PRESENT.

PART 11: MARGIN, RIGHT BUCCAL, BIOPSY

NO TUMOR PRESENT.

PART 12: TURBINATE, LEFT INFERIOR, BIOPSY

NO TUMOR PRESENT.

PART 13: NECK, RIGHT LEVEL 1, SELECTIVE DISSECTION

A. ELEVEN (11) BENIGN LYMPH NODES (0/11).

B. UNREMARKABLE SUBMANDIBULAR GLAND.

PART 14: NECK, RIGHT LEVELS 2-4, SELECTIVE DISSECTION

TWENTY-FIVE (25) BENIGN LYMPH NODES (0/25).

PART 15: NECK, LEFT LEVELS 2-4, SELECTIVE DISSECTION

TWENTY-THREE (23) BENIGN LYMPH NODES (0/23).

1 CD-0-3

carcinoma, squamous cell, keratinizing, nos

8071/3

Site: Palate, nos 805.9

lw
9/29/12

** Report Electronically Signed Out

HPA Discrepancy		☒

[page 2 of 8]
By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received unfixed in 15 parts.

Part 1 is labeled with the patient's name, initials XX and "right maxillectomy". The specimen consists of a 8.0 x 7.5 x 3.5 cm right maxillectomy consisting of 5.0 x 1.0 x 1.0 cm of maxillectomy bone with two

carious teeth and two additional portions of root. Also received is 5.0 x 2.0

portion of nasoseptum with right and left nasal cavities and a 3.0 x 2.0 x 1.0

cm segment of right ethmoid.

There is a 5.5 x 5.5 x 3.5 cm tan-gray, firm, ulcerated lesion present on the

palate. The lesion extends to 0.2 cm of the anterior gingival margin, 0.6 cm

of the posterior soft tissue 0.4 cm of the medial soft tissue and 0.3 cm of

the lateral soft tissue. The lesion extends to the deep soft tissue and

presses into the right nasal cavity and abuts the right turbinate. The lesion

does not grossly appear to extend into bone of the maxilla.

Also received are 5 tan-gray, soft to firm fragments of soft tissue ranging in

size from 1.0 x 1.0 x 0.8 cm. Digital images are taken and tissue is procured

for the head and neck spore tissue bank.

Ink code:

Black- deep soft tissue

Red- area banked

Section code:

1A - maxilla bone resection margin (decal)

1B - sinus bone superior bone margin (decal)

1C - lesion with sinus bone and right nasal cavity (decal)

1D, 1E - lesion and maxilla bone (decal)

1F - lesion and deep extension to soft tissue

1G - lesion and medial soft tissue

1H - lesion and posterior soft tissue

1I, 1J- lesion and soft tissue

1K - representative cross-section of right turbinate

1L - representative cross-sections of fragments of free-floating tissue

TIF: 31 hours

Part 2 is labeled with the patient's name, initials XX and "contents of pterygopalatine fossa right side". The specimen consists of a tan-gray, soft

to firm un-oriented fragment of tissue measuring 3.5 x 2.5 x 1.0 cm with a 1.0

x 0.5 x 0.2 cm portion of bone present. The specimen is serially cross-sectioned and entirely submitted following adequate decalcification in

decal cassettes labeled 2A and 2B.

[page 3 of 8]
TIF: 31 hours

Part 3 is labeled with the patient's name, initials XX and "right inferior orbital heme clip distal". The specimen consists of a 3.8 x 0.4 x 0.4 summary of tan-gray, soft to firm fragment of tissue. There is a Hemoclip present at the distal aspect. The proximal aspect is inked blue and the specimen is entirely frozen. Following frozen section consult the specimen is entirely submitted in cassette labeled 3AFS.

TIF: 31 hours

Part 4 is labeled with the patient's name, initials XX and "right pterygoid margin". The specimen consists of a 1.3 x 1.0 x 0.6 cm tan-gray, soft to firm fragment of tissue. Following frozen section consult the specimen is entirely submitted in cassette labeled 4 AFS.

TIF: 31 hours

Part 5 is labeled with the patient's name, initials XX and "nasopharynx". The specimen consists of a 2.0 x 1.0 x 0.5 cm tan-gray, soft to firm fragment of tissue. Following frozen section consult the specimen is entirely submitted in cassette labeled 5AFS.

TIF: 31 hours

Part 6 is labeled with the patient's name, initials XX and "right pterygoid muscle". The specimen 5 x 1.5 x 1.3 cm tan-gray, soft to firm and focally hemorrhagic portion of un-oriented muscle with adherent tan-gray firm bone measuring 1.0 x 1.0 x 0.2 cm. the specimen is serially cross-sectioned and tan-gray, firm bone with adherent red-focally hemorrhagic muscle and a 1.0 x 0.8 x 0.5 cm tan-gray, firm lesion. The specimen is entirely submitted following adequate decalcification in decal cassettes labeled 6A through 6C.

TIF: 31 hours

Part 7 is labeled with the patient's name, initials XX and "left lip margin". The specimen consists of a 4.5 x 0.3 x 0.3 cm tan-gray, soft to firm fragment of tissue. Following frozen section consult the specimen is entirely submitted in cassette labeled 7AFS.

TIF: 31 hours

Part 8 is labeled with the patient's name, initials XX and "right lip margin".

The specimen consists of a 3.1 x 0.4 x 0.3 cm tan-gray, soft and firm fragment tissue. Following frozen section consult the specimen is entirely submitted in cassette labeled 8AFS.

TIF: 31 hours

[page 4 of 8]
Part 9 is labeled with the patient's name, initials XX and "left hard palate margin". The specimen consists of a 3.8 x 0.4 x 0.2 cm tan-gray, soft and

firm fragment tissue. Following frozen section consult the specimen is entirely submitted in cassette labeled 9AFS.

TIF: 31 hours

Part 10 is labeled with the patient's name, initials XX and "soft palate margin". The specimen consists of a 3.9 x 0.3 x 0.3 cm tan-gray, soft and firm

fragment tissue. Following frozen section consult the specimen is entirely

submitted in cassette labeled 10AFS.

TIF: 31 hours

Part 11 is labeled with the patient's name, initials XX and "right buccal margin". The specimen consists of a 6.5 X 0.3 X 0.3 cm tan-gray, soft and firm

fragment tissue. There is a stitch present on the specimen. The area of the stitch is inked blue and the opposite is inked orange. Following frozen

section consult the specimen is entirely submitted in the following cassettes:

11AFS - the remainder of the frozen section of the anterior aspect

11BFS - remainder of the frozen section of the posterior aspect

TIF: 31 hours

Part 12 is labeled with the patient's name, initials XX and "left inferior turbinate". The specimen consists of a tan-gray, soft to firm fragment of

tissue measuring 3.0 x 1.0 x 0.6 cm per the specimen is serially cross-sectioned. Following adequate decalcification the specimen is entirely

submitted in decal cassette labeled 12A.

TIF: 10 hours

Part 13 is labeled with the patient's name, initials XX and "right neck dissection level 1". The specimen consists of a 7.0 x 4.0 x 2.5 cm tan-yellow, lobular portion of adipose tissue. There is a 5.0 x 3.5 x 2.0 cm

portion of tan-yellow, lobular glandular tissue present. 10 potential lymph

nodes are dissected out ranging in size from 0.5 x 0.4 x 0.3 cm to 1.7 x 1.0 x

0.6 cm. Representative sections are submitted in the following cassettes:

13A - represented cross-section of the glandular tissue

13B-13D - the potential lymph nodes are entirely submitted

TIF: 10 hours

Part 14 is labeled with the patient's name, initials XX and "right neck levels

2-4". The specimen consists of a 12.0 x 4.0 x 1.5-cm selective neck dissection. The specimen is arbitrarily divided into 3 levels and potential

lymph nodes are dissected out of each level:

[page 5 of 8]
Level #2: 14 potential lymph nodes are dissected out ranging in size from 0.2 x 0.2 x 0.1 cm to 1.5 x 0.8 x 0.4 cm.

Level #3: 12 potential lymph nodes are dissected out ranging in size from 0.2 x 0.2 to 0.2 cm to 1.0 x 0.8 x 0.6 cm.

Level #4: Six potential lymph nodes are dissected out ranging in size from 0.2 x 0.1 x 0.1 cm to 3.0 x 1.0 x 1.0 cm.

Remainder of the tissue consists of tan-yellow, lobular adipose tissue with

portions of hemorrhagic muscle and vessel.

Section code:

14A, 14B - potential lymph nodes from level 2

14C, 14D - potential lymph nodes from level 3

14E - large potential lymph node level 4

14F - potential lymph nodes level 4

TIF: 10 hours

Part 15 is labeled with the patient's name, initials XX and "left neck levels

2-4". The specimen consists of a 13.0 x 3.5 x 1.5-cm selective neck dissection. The specimen is arbitrarily divided into 3 levels and potential

lymph nodes are dissected out of each level:

Level #2: 14 potential lymph nodes are dissected out ranging in size

from 0.1 x 0.1 x 0.1 cm to 2.0 x 0.7 x 0.4 cm

Level #3: 12 potential lymph nodes are dissected out ranging in size

from 0.3 x 0.2 x 0.1 cm to 1.0 x 0.5 x 0.5 cm.

Level #4: Seven potential lymph nodes are dissected out ranging in size

from 0.2 x 0.2 x 0.2 cm to 1.0 x 0.4 x 0.2 cm

Remainder of the tissue consists of tan-yellow, lobular adipose tissue with

portions of hemorrhagic muscle and vessel.

Section code:

15A, 15B - potential lymph nodes from level 2

15C, 15D - potential lymph nodes from level 3

15E, 15F - potential lymph nodes level 4

TIF: 10 hours

GROSSED BY:

INTRAOPERATIVE CONSULTATION:

3 AFS: RIGHT INFRAORBITAL NERVE (frozen section) -

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

C. NO TUMOR PRESENT

4 AFS: RIGHT PTERYGOID MARGIN (frozen section) -

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

C. NO TUMOR PRESENT

5 AFS: NASOPHARYNX (frozen section) -

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

[page 6 of 8]
C. NO TUMOR PRESENT

7 AFS: LEFT LIP MARGIN (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

8 AFS: RIGHT LIP SHAVE MARGIN (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

9 AFS: LEFT HARD PALATE SHAVE MARGIN (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

10 AFS: SOFT PALATE SHAVE MARGIN (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

11 AFS: RIGHT BUCCAL SHAVE MARGIN (ANTERIOR) (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

11 BFS: RIGHT BUCCAL SHAVE MARGIN (frozen section) -
A. SUFFICIENT FOR ANCILLARY STUDIES.
B. BENIGN.
C. NO TUMOR PRESENT

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the _____, Department of Pathology, as required by the CLIA

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

[page 7 of 8]
SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY
GLAND

TUMORS

SPECIMEN TYPE: Resection: Right maxillectomy
TUMOR SITE: Oral Cavity
TUMOR SIZE: Greatest dimension: 5.5 cm
HISTOLOGIC TYPE: Squamous cell carcinoma, conventional
HISTOLOGIC GRADE: G2
PRIMARY TUMOR (pT): pT4b
REGIONAL LYMPH NODES (pN): pN0
Number of regional lymph nodes examined: 59
Number of regional lymph nodes involved: 0
DISTANT METASTASIS (pM): pMX
MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
Absent
PERINEURAL INVASION: Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Mouth cancer
PROCEDURE: Maxillectomy
SPECIFIC CLINICAL QUESTION: Not answered
OUTSIDE TISSUE DIAGNOSIS: Not answered
PRIOR MALIGNANCY: Not answered
CHEMOTHERAPY: Not answered
ORGAN TRANSPLANT: Not answered
IMMUNOSUPPRESSION: Not answered
OTHER DISEASES: Not answered
HISTO TISSUE SUMMARY/SLIDES REVIEWED:
Part 1: Right Maxillectomy

Taken:

Stain/	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J
H&E x 1	K
H&E x 1	L

Part 2: Content of Pteryqal Palatal Fossa Right Side

Taken:

Stain/	Block
Decal x 1	A
H&E x 1	A
H&E x 1	B

Part 3: Right Infraorbital Nerve

Taken:

Stain,	Block
H&E x 1	AFS

Part 4: Right Pterygoid Margin

[page 8 of 8]
Taken:
Stain/ Block
H&E x 1 AFS
Part 5: Nasopharynx
Taken:
Stain/ Block
H&E x 1 AFS
Part 6: Right Pterygoid Muscle
Taken:
Stain Block
Decal x 1 A
H&E x 1 A
H&E x 1 B
H&E x 1 C
Part 7: Left Lip Margin
Taken:
Stain, Block
H&E x 1 AFS
Part 8: Right Lip Margin
Taken:
Stain/ Block
H&E x 1 AFS
Part 9: Left Hard Palate Margin
Taken:
Stain/ Block
H&E x 1 AFS
Part 10: Soft Palate Margin. Left Side
Taken:
Stain Block
H&E x 1 AFS
Part 11: Right Buccal Margin
Taken:
Stain, Block
H&E x 1 AFS
H&E x 1 BFS
Part 12: Turbinate, Left Inferior
Taken:
Stain, Block
Decal x 1 A
H&E x 1 A
Part 13: Neck Dissection, Right Level 1
Taken:
Stain/ Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
Part 14: Neck Dissection, Right Level 2-4
Taken:
Stain/ Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
Part 15: Neck Dissection, Left Level 2-4

Source: NCI Genomic Data Commons file 2fec2dcf-01c7-4bbb-8229-25b4b7ad1b7d (TCGA-CN-A49A.38A7951F-DDA7-4F2E-BF50-976459D3048C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).